EXCEPTIONAL_RESPONDERS case ER-ABEO — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c2179d16-d6ce-4741-bc50-95a2bf5d710d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1935; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 69.2 years (25,275 days); Year of diagnosis: 2004; AJCC staging edition: 6th; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Days to last follow up: 3,911 days (10.7 years); Days to best overall response: 383 days (1.0 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Fluorouracil; Days to treatment start: 71 days; Days to treatment end: 232 days.
   Treatment given: Therapeutic agents: Leucovorin Calcium + Oxaliplatin; Days to treatment start: 71 days; Days to treatment end: 230 days.
   Treatment given: Therapeutic agents: Bevacizumab; Days to treatment start: 181 days; Days to treatment end: 230 days.

Follow-up (1 entry)
- Days to follow up: 3,911 days (10.7 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 65 days; Days progression-free: 3,911 days (10.7 years).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABEO-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
  Slide ER-ABEO-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample ER-ABEO-TTM2-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
  Slide ER-ABEO-TTM2-A-1-0-S1: Section location: Top; Percent tumor cells: 15; Percent tumor nuclei: 10; Percent normal cells: 85; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-ABEO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-ABEO-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 72; Percent tumor nuclei: 65; Percent normal cells: 10; Percent necrosis: 18; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 1.
